Somatic mutation profile of tumor specimen TCGA-XY-A8S3-01B (aliquot TCGA-XY-A8S3-01B-11D-A435-10) from TCGA case TCGA-XY-A8S3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 24.2 years (8,835 days).
Specimen TCGA-XY-A8S3-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39f6789c-ef77-4289-9b7f-3608c6c98874.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XY-A8S3-10A (Blood Derived Normal), aliquot TCGA-XY-A8S3-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e97ef5fb-15c1-402f-a908-94fb75ee5da3

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K6 | c.2289C>A p.H763Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62890870; called by mutect2, varscan2
- NEK10 | c.1977C>G p.N659K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58282027; called by muse, mutect2, varscan2
- CEP290 | c.498C>G p.N166K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TREML4 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- NRXN2 | c.4386G>A p.T1462= | Silent (SNP) | VAF 12/13 reads (92%) | called by muse, mutect2, varscan2
- IGHM | c.1300+33A>G | Intron (SNP) | VAF 16/134 reads (12%) | called by mutect2, varscan2
